Gene-level copy-number profile of tumor specimen TCGA-04-1646-01A from TCGA case TCGA-04-1646, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.8 years (22,207 days).
Specimen TCGA-04-1646-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.89ba5753-d63d-4a87-9f18-078d2dd315ee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1646-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/47afbf41-41fc-44a2-89ff-67756109adea

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7; copy number 2: 24,135; copy number 3: 8,362; copy number 4: 21,584; copy number 5: 1,902; copy number 6: 3,135; copy number 7: 169; copy number 8: 377; copy number 9: 79; copy number 10: 13; copy number 17: 3; copy number 19: 7; copy number 29: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1646-01A-01D-0577-01): tumor purity 0.97, ploidy 1.7, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,731 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:46,040,140–46,176,488, 2 genes, copy number 6 (within-gene range 3–6): PIK3R3, P3R3URF-PIK3R3.
- chr1:46,104,950–46,365,152, 10 genes, copy number 6 (within-gene range 3–6): AL358075.3, AL358075.2, TSPAN1, P3R3URF, POMGNT1, LURAP1, RAD54L, LRRC41, UQCRH, NSUN4.
- chr1:143,343,180–149,846,486, 226 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr2:38,203,363–38,603,586, 11 genes, copy number 6: AC009229.1, RPL7P12, GAPDHP25, ATL2, LINC02613, AC016995.1, LINC01883, RPLP0P6, AC011247.2, HNRNPLL, AC011247.1.
- chr2:38,668,202–38,671,421, 1 gene, copy number 6: AC074366.1.
- chr2:101,696,850–102,452,565, 15 genes, copy number 6 (within-gene range 4–6): MAP4K4, LINC01127, IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1.
- chr2:174,326,027–175,184,607, 26 genes, copy number 6: LINC01305, AC018470.1, SP9, CIR1, SCRN3, GPR155, AC010894.1, RPA3P1, AC010894.4, AC010894.2, RNU6-5P, WIPF1, AC010894.3, H3P6, CHRNA1, CHN1, RNU6-763P, RNU6-1290P, RPL21P31, ATF2, AC007435.1, MIR933, AC096649.1, ATP5MC3, Y_RNA, RPS15AP14.
- chr4:49,096–20,037,972, 406 genes, copy number 6–10 (broad region; genes not listed).
- chr4:69,051,363–73,620,631, 83 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:32,911,493–33,045,445, 2 genes, copy number 6 (within-gene range 2–6): RNU6-663P, AC090204.1.
- chr8:37,762,595–40,897,833, 73 genes, copy number 6–8 (within-gene range 3–8) (broad region; genes not listed).
- chr8:41,653,220–145,066,685, 1,598 genes, copy number 5–6 (broad region; genes not listed).
- chr12:54,802,746–59,130,875, 210 genes, copy number 6–8 (broad region; genes not listed).
- chr12:59,450,673–73,208,317, 246 genes, copy number 6–29 (broad region; genes not listed).
- chr14:68,605,396–68,869,951, 10 genes, copy number 6: AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1, MAGOH3P, BLZF2P.
- chr14:74,614,693–106,875,071, 933 genes, copy number 6–8 (broad region; genes not listed).
- chr17:39,461,486–39,864,312, 17 genes, copy number 5 (within-gene range 2–5): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1.
- chr18:53,237,101–53,237,190, 1 gene, copy number 6: MIR4528.
- chr19:8,806,170–9,936,552, 58 genes, copy number 6–10 (within-gene range 2–10): ZNF558, AC008734.1, MBD3L1, AC008734.2, MUC16, BOLA3P2, OR1M4P, OR1M1, OR7G2, OR7G1, OR7G15P, OR7G3, ZNF317, OR7D2, ELOCP29, OR7E16P, OR7E25P, OR7D4, OR7D1P, OR7E24, OR7E18P, OR7E19P, OR7H1P, ZNF699, AC011451.1, ZNF559, ZNF559-ZNF177, AC011451.2, ZNF177, AC011451.3, ZNF266, AC011451.4, ZNF560, AC008567.2, AC008567.3, AC008567.1, ZNF426, ZNF426-DT, ZNF121, ZNF561, ZNF561-AS1, ZNF562, RPS4XP22, ZNF812P, AC008759.3, AC008759.1, AC008759.2, ZNF846, AC008752.3, UBE2L4, AC008752.1, FBXL12, SNORA70, RPL10P15, UBL5, AC008752.2, PIN1, OLFM2.
- chr19:11,296,139–19,320,509, 469 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:27,638,483–30,228,715, 63 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–6,528,459, 197 genes, copy number 6–9 (broad region; genes not listed).
- chr20:8,077,251–8,968,360, 1 gene, copy number 7 (within-gene range 4–7): PLCB1.
- chr20:8,831,186–13,996,443, 67 genes, copy number 6–9 (broad region; genes not listed).
- chr20:14,003,508–14,352,425, 5 genes, copy number 6: RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P.
- chr20:15,021,553–15,280,873, 3 genes, copy number 6: RNU6-1159P, RNU6-115P, RNA5SP475.
- chr20:19,208,652–20,056,046, 10 genes, copy number 6: AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1.
- chr20:20,094,401–20,095,684, 1 gene, copy number 6: AL035454.1.
- chr20:23,439,685–25,585,531, 61 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:30,278,906–39,039,723, 293 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:40,717,257–47,656,877, 191 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:48,494,234–57,712,780, 170 genes, copy number 6 (broad region; genes not listed).
- chr20:58,069,054–58,911,192, 29 genes, copy number 6 (within-gene range 4–6): AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2.
- chr20:59,460,619–60,653,784, 14 genes, copy number 6 (within-gene range 4–6): PIEZO1P1, AL389889.2, AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1, MIR646HG, MIR646.
- chr20:61,252,261–64,313,132, 144 genes, copy number 6–7 (broad region; genes not listed).
- chr21:14,676,698–20,430,762, 85 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
